Gene-level copy-number profile of tumor specimen TCGA-PD-A5DF-01A from TCGA case TCGA-PD-A5DF, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 58.6 years (21,414 days).
Specimen TCGA-PD-A5DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.1de7d28b-e555-438b-951d-d79792e13177.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PD-A5DF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/02eab016-59a7-4cb2-b5bd-cb97437c9d3e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 4,921; copy number 2: 50,390; copy number 3: 4,411; copy number 4: 16; copy number 5: 28; copy number 6: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PD-A5DF-01A-11D-A27H-01): tumor purity 0.73, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:96,889,315–96,914,995, 2 genes: NDUFAF4, RN7SL509P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 78 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,234,774–9,614,877, 9 genes, copy number 5: H6PD, SPSB1, BX323043.1, LINC02606, RNA5SP40, AL928921.1, SLC25A33, AL954705.1, TMEM201.
- chr16:25,236,001–25,454,647, 5 genes, copy number 5 (within-gene range 3–5): ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39.
- chr16:26,302,064–26,729,126, 5 genes, copy number 5: AC009158.1, AC130464.1, AC002331.1, LINC02195, AC009035.1.
- chr16:31,355,134–31,569,475, 24 genes, copy number 6: ITGAX, AC093520.2, ITGAD, AC093520.1, COX6A2, AC026471.5, ZNF843, AC026471.4, AC026471.1, ARMC5, AC026471.6, TGFB1I1, SLC5A2, AC026471.3, RUSF1, AC026471.2, AHSP, LINC02190, AC106730.1, VN1R64P, VN1R65P, FRG2KP, AC106730.2, YBX3P1.
- chr20:22,220,554–22,585,455, 7 genes, copy number 5: AL035258.1, LINC01427, AL049737.1, AL121912.1, AL133464.1, LINC00261, FOXA2.
- chr20:24,063,255–24,226,013, 2 genes, copy number 5 (within-gene range 2–5): LINC01721, AL110503.1.
- chr20:61,953,469–62,551,526, 26 genes, copy number 6: TAF4, MIR1257, AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1.

Autosomal genes at a single copy (total copy number 1): 4,921. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
